Gene-level copy-number profile of tumor specimen C3N-02575-01 (profiled together with C3N-02575-02) from CPTAC case C3N-02575, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 70.0 years (25,569 days).
Specimen C3N-02575-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c7725c31-eba5-44bc-8b18-0a729adb0c62.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02575-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/f2c39f11-24e6-4b43-95c3-38ce791f0b2a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 550; copy number 2: 14,310; copy number 3: 8,395; copy number 4: 26,906; copy number 5: 3,388; copy number 6: 870; copy number 7: 1,114; copy number 8: 1,152; copy number 9: 624; copy number 10: 750; copy number 11: 522; copy number 12: 152; copy number 13: 103; copy number 14: 4; copy number 15: 8; copy number 17: 9; copy number 25: 10; copy number 29: 9; copy number 37: 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:235,773,855–235,783,387, 1 gene (within-gene range 0–3): AC064874.1.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr10:4,962,436–5,135,226, 8 genes (within-gene range 0–4): U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P.
- chr10:87,859,158–87,971,930, 4 genes: KLLN, PTEN, AC063965.2, RPL11P3.
- chr13:68,289,679–68,331,613, 3 genes: ELL2P3, HNRNPA1P18, RPL37P21.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:34,528,290–34,528,371, 1 gene (within-gene range 0–2): MIR1233-2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,192 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:87,226,189–118,810,836, 349 genes, copy number 10–13 (broad region; genes not listed).
- chr3:142,306,607–188,003,990, 735 genes, copy number 9–11 (broad region; genes not listed).
- chr3:188,941,715–189,897,276, 6 genes, copy number 9 (within-gene range 7–9): TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1.
- chr5:58,198–4,147,429, 92 genes, copy number 10–14 (broad region; genes not listed).
- chr5:4,451,930–4,866,311, 1 gene, copy number 10 (within-gene range 8–10): AC106799.2.
- chr5:4,640,731–41,510,628, 515 genes, copy number 10–12 (broad region; genes not listed).
- chr7:93,424,486–113,146,330, 425 genes, copy number 11–37 (broad region; genes not listed).
- chr10:79,825,902–79,827,602, 1 gene, copy number 10 (within-gene range 8–10): AL135925.1.
- chr16:32,356,981–32,380,049, 2 genes, copy number 13: AC133548.1, ACTR3BP3.
- chr19:37,823,722–39,255,269, 66 genes, copy number 9–12 (within-gene range 8–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 40. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
